Somatic mutation profile of tumor specimen TCGA-FU-A40J-01A (aliquot TCGA-FU-A40J-01A-11D-A243-09) from TCGA case TCGA-FU-A40J, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 38.8 years (14,182 days).
Specimen TCGA-FU-A40J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83986358-7da5-41b3-88be-920918f3756e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A40J-10A (Blood Derived Normal), aliquot TCGA-FU-A40J-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc0071e-0060-4298-8fbe-252ad04c3a32

The open-access MAF lists 208 somatic variants for this specimen: 157 protein-altering or splice-affecting, 42 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 42, Nonsense Mutation 12, Intron 6, Frame Shift Del 4, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2305G>C p.D769H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913468, COSV54062373, COSV54062425, COSV54063143; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TMEM131 | c.3955G>C p.E1319Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2, varscan2
- ABCC10 | c.159G>C p.P53= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as COSV55092088; called by muse, varscan2
- ABCC12 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60916719; called by muse, mutect2, varscan2
- ADGRV1 | c.8834G>A p.G2945D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV67991923; called by mutect2, varscan2
- ANGPTL3 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV52016125; called by muse, mutect2, varscan2
- AP002748.5 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV100567767, COSV59150804; called by muse, mutect2, varscan2
- ARAF | c.896C>G p.S299* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV51694322; called by muse, mutect2, varscan2
- ARGFX | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777806670, COSV57683352; called by muse, mutect2, varscan2
- ARHGAP6 | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV57300368; called by muse, mutect2, varscan2
- ARRDC2 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55845588; called by muse, mutect2, varscan2
- ARRDC2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as COSV55845599; called by muse, mutect2, varscan2
- ASB18 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68960956; called by muse, mutect2, varscan2
- ASPM | c.6686G>C p.R2229T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs745714332, COSV54135319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH1 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs748491382, COSV54520292; called by muse, mutect2, varscan2
- BCORL1 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.076); catalogued as COSV54402815; called by muse, mutect2, varscan2
- BCORL1 | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV54402835; called by muse, mutect2, varscan2
- BEST2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV50373724; called by muse, mutect2, varscan2
- C19orf73 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV55521088; called by muse, mutect2, varscan2
- C22orf23 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV50778495; called by muse, mutect2, varscan2
- C9orf135 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101019904, COSV65877302; called by muse, mutect2, varscan2
- CACNA1B | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV53140698, COSV53150165; called by muse, mutect2, varscan2
- CACNA1D | c.5930C>T p.S1977L (on ENST00000350061 / NM_001128840.3; = p.S1997L on NM_000720.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.009); catalogued as rs202077075, COSV55441250; called by muse, mutect2, varscan2
- CCDC114 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV59556003; called by muse, mutect2, varscan2
- CCDC115 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.97); PolyPhen benign (0.083); catalogued as rs1271656812, COSV52092413; called by muse, mutect2, varscan2
- CCDC180 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as COSV63833447; called by muse, mutect2, varscan2
- CCP110 | c.1717A>T p.N573Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66817614; called by muse, mutect2, varscan2
- CELF5 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV53013857; called by muse, mutect2, varscan2
- CELSR1 | c.6883G>C p.E2295Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV53096356; called by muse, mutect2, varscan2
- CSNK1G3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV62056091; called by muse, mutect2, varscan2
- CST9L | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.157); catalogued as rs1411885637, COSV65408143; called by muse, mutect2, varscan2
- CTCF | c.1514G>C p.R505T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); catalogued as COSV50495569; called by muse, mutect2, varscan2
- DAZAP1 | c.417C>T p.V139= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99245168; called by muse, mutect2, varscan2
- DBN1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52791706; called by muse, mutect2, varscan2
- DCST1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV55061839; called by muse, mutect2, varscan2
- DMD | c.4852C>T p.Q1618* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as CM022951, COSV63778555; called by muse, mutect2, varscan2
- DNAH1 | c.12382C>G p.L4128V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV56234859; called by muse, mutect2, varscan2
- DNAH7 | c.8238G>A p.M2746I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56764338; called by muse, mutect2, varscan2
- EFHD1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV51133764; called by muse, mutect2, varscan2
- EHBP1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs756892360, COSV50429825; called by mutect2, varscan2
- ENTHD1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57318989; called by muse, mutect2, varscan2
- EPB41L1 | c.178-1G>C p.X60_splice | Splice Site (SNP) | VAF 51/85 reads (60%) | catalogued as COSV52441998; called by muse, mutect2, varscan2
- ETV4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, mutect2, varscan2
- FAM122B | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53232088; called by muse, mutect2, varscan2
- FCRL5 | c.1999A>T p.R667W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62518205; called by muse, mutect2, varscan2
- GABRB2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50917841; called by muse, mutect2, varscan2
- GGA3 | c.514G>A p.E172K (on ENST00000537686 / NM_138619.4; = p.E139K on NM_014001.5) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372068946; called by muse, mutect2, varscan2
- GNA13 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101457496; called by muse, mutect2, varscan2
- GNAQ | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs769002669, COSV54121313; called by muse, mutect2, varscan2
- GPKOW | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV50244438, COSV50244584; called by muse, mutect2, varscan2
- GPR1 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101329856; called by muse, mutect2
- GSDMA | c.48C>A p.N16K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs747158297, COSV56978874; called by muse, mutect2, varscan2
- GUCY2D | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs144151076; called by muse, mutect2, varscan2
- HCRTR1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as rs201416198, COSV65483816; called by muse, mutect2, varscan2
- HEATR4 | c.2936A>G p.D979G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.254); catalogued as rs770323501, COSV100620221, COSV58575879; called by muse, mutect2, varscan2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, varscan2
- IFI35 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55896802; called by muse, mutect2, varscan2
- INPP1 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV59417055; called by muse, mutect2
- INSM1 | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs755151592, COSV100044604, COSV100044826, COSV59605187; called by muse, varscan2
- JKAMP | c.58C>G p.Q20E (on ENST00000554271 / NM_001284201.1; = p.Q6E on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV54200768, COSV99039152; called by muse, mutect2, varscan2
- JUND | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53254833; called by muse, mutect2, varscan2
- KANK1 | c.4027C>G p.P1343A | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66528385, COSV66528685; called by muse, mutect2, varscan2
- KCNQ3 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66477839; called by muse, mutect2, varscan2
- KCTD2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as COSV56903302; called by muse, mutect2, varscan2
- KDM3A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs760305076, COSV57224424; called by muse, mutect2, varscan2
- KIAA0100 | c.4373G>A p.W1458* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV66495480; called by muse, mutect2, varscan2
- KIAA1549L | c.473A>G p.E158G (on ENST00000321505; = p.E455G on NM_012194.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV55778659; called by muse, mutect2, varscan2
- KLHL8 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56748906; called by muse, mutect2, varscan2
- KRT2 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1459622656, COSV59012003; called by muse, mutect2, varscan2
- LAMP2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV52353626; called by muse, mutect2, varscan2
- LCMT2 | c.1869G>C p.L623F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59791372; called by muse, mutect2, varscan2
- LMX1A | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99672868; called by muse, mutect2, varscan2
- MAGEA6 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV61449160; called by muse, mutect2, varscan2
- MLIP | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as COSV51434433; called by muse, mutect2, varscan2
- MTMR1 | c.1650C>G p.F550L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100953138; called by muse, mutect2, varscan2
- MTRF1 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV53482005; called by muse, mutect2, varscan2
- MUC17 | c.9386C>A p.P3129H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100074430; called by muse, mutect2
- MYBPC2 | c.2448C>G p.I816M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.157); catalogued as rs918614329, COSV63098431; called by muse, mutect2, varscan2
- MYH10 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52613826, COSV99345916; called by muse, mutect2, varscan2
- MYH3 | c.5740G>A p.A1914T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1169141194, COSV56868308; called by muse, mutect2
- NAALADL2 | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV69158996; called by muse, mutect2, varscan2
- NAB2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55667292; called by muse, mutect2, varscan2
- NGF | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as rs199511298; called by muse, mutect2, varscan2
- NID2 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV53500666; called by muse, mutect2, varscan2
- NKX2-2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65819876; called by muse, mutect2, varscan2
- NOL4 | c.675G>C p.M225I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV52339486, COSV99307789; called by muse, mutect2
- OBSCN | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV52808176; called by muse, mutect2, varscan2
- OGDHL | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777515897, COSV65100677, COSV65104914; called by muse, mutect2
- OR2T27 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV61283075; called by muse, mutect2, varscan2
- OR56B4 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57205198; called by muse, mutect2, varscan2
- PAAF1 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60156666; called by muse, mutect2, varscan2
- PCDHB4 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52025314; called by muse, mutect2
- PDZRN3 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs748911659, COSV55210659; called by muse, mutect2, varscan2
- PHC2 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57106618; called by muse, mutect2, varscan2
- PLCB2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53036177; called by muse, mutect2, varscan2
- PLEKHO1 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782338607, COSV50310998; called by muse, mutect2, varscan2
- PLXNB3 | c.3391G>T p.V1131L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV62800545; called by muse, mutect2, varscan2
- POLR1A | c.4615G>C p.D1539H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55697263; called by muse, mutect2, varscan2
- PPM1G | c.594A>C p.E198D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV59770974; called by muse, mutect2, varscan2
- PTPRG | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.723); catalogued as rs1226700841, COSV55630902; called by muse, mutect2, varscan2
- R3HCC1L | c.2191del p.E731Sfs*9 (on ENST00000612478 / NM_001256619.2; = p.E717Sfs*9 on NM_014472.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as COSV100107382; called by pindel, varscan2
- RABL6 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61038902; called by muse, mutect2, varscan2
- RNF213 | c.11133C>G p.F3711L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60411544; called by muse, mutect2
- ROPN1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV51740708; called by muse, mutect2
- RPS13 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV57180427; called by muse, mutect2, varscan2
- RYR1 | c.9278G>A p.R3093H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as rs1414706865, COSV62105460; called by muse, mutect2, varscan2
- SALL3 | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV73305868, COSV73306320; called by muse, mutect2, varscan2
- SDCCAG8 | c.2072G>C p.R691T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV59414389; called by muse, mutect2, varscan2
- SEC23A | c.1828C>G p.Q610E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56977123; called by muse, mutect2, varscan2
- SEC31A | c.1787C>T p.A596V (on ENST00000355196 / NM_001318120.1; = p.A557V on NM_016211.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52348801; called by muse, mutect2, varscan2
- SENP5 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60209149; called by muse, mutect2, varscan2
- SERPINA7 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs375380232, COSV59666841; called by muse, mutect2, varscan2
- SERTAD3 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV59325582; called by muse, mutect2, varscan2
- SETBP1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs778015039, COSV56331626; called by muse, mutect2, varscan2
- SEZ6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as COSV57983530; called by muse, mutect2, varscan2
- SORL1 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99494881; called by muse, mutect2
- SOX3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV65168511; called by muse, mutect2, varscan2
- SPRED1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV54438066; called by muse, mutect2, varscan2
- SRR | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766816485, COSV56786413; called by muse, mutect2, varscan2
- SRRM2 | c.4502C>G p.S1501* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV57075866, COSV57078581; called by muse, mutect2, varscan2
- STXBP3 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV64183146; called by muse, mutect2, varscan2
- SUPT20H | c.814G>C p.E272Q (on ENST00000350612 / NM_001014286.3; = p.E273Q on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV62248954; called by muse, mutect2, varscan2
- TCHH | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV64276757; called by muse, mutect2, varscan2
- TEX10 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66517635; called by muse, mutect2, varscan2
- TIMELESS | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57513930; called by muse, mutect2
- TLR3 | c.2421C>G p.I807M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.68); catalogued as COSV57167475, COSV57168595, COSV57169136; called by muse, mutect2, varscan2
- TMEM18 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV55244734; called by muse, mutect2, varscan2
- TNPO1 | c.2484G>T p.M828I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV61523245; called by muse, mutect2, varscan2
- TOMM34 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100861923; called by muse, mutect2, varscan2
- TOX | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV63841958; called by muse, mutect2, varscan2
- TPD52L2 | c.354G>C p.E118D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV53863779; called by muse, mutect2, varscan2
- TPR | c.6274C>G p.Q2092E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.281); catalogued as COSV66603686; called by muse, mutect2, varscan2
- TPSAB1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs757030119, COSV58783040; called by muse, mutect2, varscan2
- TUT4 | c.3248G>C p.R1083T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57112493, COSV57115646, COSV57117977; called by muse, mutect2, varscan2
- USP17L2 | c.849C>G p.F283L | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61556368; called by muse, mutect2, varscan2
- USP44 | c.2011T>C p.Y671H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760344021, COSV51565904; called by muse, mutect2, varscan2
- VAV3 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58386671, COSV58388872; called by muse, mutect2, varscan2
- VIP | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100923944, COSV65889398; called by muse, mutect2, varscan2
- VMP1 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51867514; called by muse, mutect2, varscan2
- WDR31 | c.667G>C p.A223P (on ENST00000374193 / NM_001006615.3; = p.A222P on NM_145241.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV59147256; called by muse, mutect2, varscan2
- ZBTB33 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV58533644, COSV58534704; called by muse, mutect2, varscan2
- ZFHX3 | c.9976G>A p.A3326T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs781682309, COSV51715822; called by mutect2, varscan2
- ZNF568 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV61742479; called by muse, mutect2, varscan2
- ZNF626 | c.353T>A p.I118K | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV74130249; called by muse, mutect2, varscan2
- ZNF630 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV52097681; called by muse, mutect2, varscan2
- ZNF804B | c.4018G>T p.E1340* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60844447; called by muse, mutect2, varscan2
- ZNF813 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV67175682, COSV67177534; called by muse, mutect2, varscan2
- ZNF99 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV68056246; called by muse, mutect2, varscan2
- ZRANB3 | c.3209C>G p.S1070* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99924301; called by muse, mutect2
- ENTPD6 | c.1101_1102del p.R367Sfs*91 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by pindel, varscan2
- MAEL | c.373_376dup p.L126Rfs*7 | Frame Shift Ins (INS) | VAF 7/53 reads (13%) | called by mutect2, pindel
- MAP3K6 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOD2 | c.1875G>T p.L625F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2
- RNF44 | c.1226del p.K409Sfs*3 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- SERPINB3 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2
- ST3GAL3 | c.132_156del p.H44Qfs*17 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | called by mutect2, pindel
- ACADSB | c.603C>T p.L201= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV62551246; called by muse, mutect2, varscan2
- ADAM12 | c.2421G>A p.L807= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV64134379; called by muse, mutect2, varscan2
- ADGRA2 | c.2265G>C p.L755= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV55104936; called by muse, mutect2, varscan2
- AFF4 | c.102C>G p.L34= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs913881152, COSV54797825; called by muse, mutect2, varscan2
- AL592490.1 | c.999T>G p.A333= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV101308249; called by muse, mutect2
- ATP9B | c.2988G>A p.P996= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs749884882, COSV100303321; called by muse, mutect2, varscan2
- BCO2 | c.1593G>C p.G531= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100730422; called by muse, mutect2, varscan2
- BPTF | c.8259G>A p.L2753= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100075617; called by muse, mutect2, varscan2
- C6orf89 | c.303C>T p.I101= (on ENST00000373685; = p.I108= on NM_152734.4) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV62102780; called by muse, mutect2, varscan2
- CAD | c.4677C>T p.L1559= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1236166837, COSV99255454; called by muse, mutect2, varscan2
- CELSR1 | c.6138C>T p.L2046= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs370545626; called by muse, mutect2, varscan2
- CSMD1 | c.336G>A p.V112= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV68237607; called by muse, mutect2
- CST1 | c.279A>T p.I93= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV59055984; called by muse, mutect2, varscan2
- DAB1 | c.1011C>T p.G337= (on ENST00000371231; = p.G304= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1482139714, COSV100976322, COSV64691347; called by muse, mutect2
- DESI1 | c.51C>G p.S17= | Silent (SNP) | VAF 55/289 reads (19%) | catalogued as COSV54355039; called by muse, mutect2, varscan2
- ENOSF1 | c.1206G>C p.L402= (on ENST00000340116 / NM_001354066.2; = p.L368= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51894585; called by muse, mutect2, varscan2
- ETV5 | c.1428C>T p.S476= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs761631963, COSV60503067; called by muse, mutect2, varscan2
- EYA1 | c.1308C>T p.F436= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV58169901; called by muse, mutect2, varscan2
- FBXO31 | c.1593C>T p.L531= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV61150375; called by muse, mutect2, varscan2
- GPKOW | c.951C>T p.L317= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV50244409; called by muse, mutect2, varscan2
- H1-5 | c.444G>A p.A148= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58900863; called by muse, mutect2, varscan2
- HDAC7 | c.2650C>T p.L884= (on ENST00000427332; = p.L923= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV50401531; called by muse, mutect2, varscan2
- HOXB7 | c.339G>A p.Q113= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1221430311, COSV53311215; called by muse, mutect2, varscan2
- IFI35 | c.144C>T p.I48= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV55896797, COSV99887721; called by muse, mutect2, varscan2
- IGSF9B | c.144C>T p.I48= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58071076; called by muse, mutect2, varscan2
- MUC16 | c.42498G>A p.L14166= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV66695191; called by muse, mutect2, varscan2
- MYH2 | c.4725G>A p.K1575= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV55444742; called by muse, mutect2, varscan2
- MYOC | c.1404G>A p.K468= | Silent (SNP) | VAF 35/205 reads (17%) | catalogued as rs766884379, COSV50677026; called by muse, mutect2, varscan2
- OR52H1 | c.450C>T p.I150= (on ENST00000322653; = p.I156= on NM_001005289.1) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59506022; called by muse, mutect2
- OR7A5 | c.159C>T p.S53= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV59235144; called by muse, mutect2, varscan2
- PCYT1A | c.651G>A p.A217= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs946538204, COSV53059229; called by muse, mutect2, varscan2
- PDK4 | c.723C>T p.I241= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1303305862, COSV50010636, COSV50011879; called by muse, mutect2
- PTCD3 | c.1965C>T p.I655= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99606523; called by muse, mutect2
- SACS | c.4014G>A p.K1338= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV66544806; called by muse, mutect2, varscan2
- SCG2 | c.1107C>G p.L369= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV59541239; called by muse, mutect2, varscan2
- SLC5A2 | c.216C>T p.F72= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs149913553, CM034966; called by muse, mutect2, varscan2
- TCHH | c.525G>T p.R175= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV64272650, COSV64276751; called by muse, mutect2, varscan2
- TP73 | c.459C>T p.C153= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV60704706; called by muse, mutect2, varscan2
- TSHZ1 | c.720C>T p.F240= (on ENST00000580243 / NM_001308210.2; = p.F195= on NM_005786.6) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV59014449; called by muse, mutect2, varscan2
- WDR64 | c.951C>G p.V317= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV63798774; called by muse, mutect2, varscan2
- XIRP1 | c.2538G>A p.L846= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV61140143; called by muse, mutect2
- ZDHHC13 | c.1746G>A p.Q582= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV67981626; called by muse, mutect2
- AL353804.6 | chrX:73826412 G>A | 3'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- CACNA1D | c.1220+633G>C | Intron (SNP) | VAF 23/186 reads (12%) | catalogued as COSV55458699; called by muse, mutect2, varscan2
- DPP6 | c.627+21153G>C | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59634623; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+465G>A | Intron (SNP) | VAF 12/92 reads (13%) | catalogued as COSV56194815; called by muse, mutect2, varscan2
- MACF1 | c.15832-10482C>T | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as COSV57135524; called by muse, mutect2, varscan2
- MAP4 | c.1999+5607G>C | Intron (SNP) | VAF 6/114 reads (5%) | catalogued as COSV99275947; called by muse, mutect2
- MIR519B | n.18G>C | RNA (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- RAP1GAP | c.-149+4019C>T | Intron (SNP) | VAF 4/60 reads (7%) | catalogued as rs1322900532, COSV100523049; called by muse, mutect2
- Y_RNA | chr14:50083995 C>T | 5'Flank (SNP) | VAF 11/41 reads (27%) | catalogued as rs746597119; called by muse, mutect2, varscan2
